Somatic mutation profile of tumor specimen TCGA-BR-8483-01A (aliquot TCGA-BR-8483-01A-31D-2394-08) from TCGA case TCGA-BR-8483, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 59.5 years (21,731 days).
Specimen TCGA-BR-8483-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323096f8-2112-4ed7-954f-d72e8e5e0c41.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8483-10A (Blood Derived Normal), aliquot TCGA-BR-8483-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27f48a5f-794a-428f-8a02-8ae4d8aa078f

The open-access MAF lists 134 somatic variants for this specimen: 100 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 4, Frame Shift Ins 3, Splice Region 2, RNA 1, 3'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP7B1 | c.995A>C p.K332T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as rs1004981575, COSV59582892, COSV59590977; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 79/106 reads (75%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.5076C>A p.F1692L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV70041861; called by muse, mutect2, varscan2
- ABCA13 | c.12926G>A p.R4309H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771458235, COSV68947596; called by muse, mutect2, varscan2
- ACACB | c.5391T>G p.F1797L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV58144088; called by muse, mutect2, varscan2
- ADCY3 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV53171846; called by muse, mutect2, varscan2
- ADSL | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1270510045, COSV53409794; called by muse, mutect2, varscan2
- AKR1B10 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV62056447; called by muse, mutect2, varscan2
- AOX1 | c.1284C>A p.F428L | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.191); catalogued as COSV65983665; called by muse, mutect2, varscan2
- ARMC4 | c.2252+1G>C p.X751_splice | Splice Site (SNP) | VAF 42/205 reads (20%) | catalogued as rs943365172, COSV59471943; called by muse, mutect2, varscan2
- ASTN2 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV57751179; called by muse, mutect2, varscan2
- CACNA1C | c.6329C>T p.A2110V (on ENST00000399634 / NM_001167625.1; = p.A2039V on NM_000719.7) | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as rs549476254, COSV59708098, COSV59761534; called by muse, mutect2
- CADPS | c.3464A>G p.E1155G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV51898582; called by muse, mutect2
- COL22A1 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs776233435, COSV100276848, COSV57355925; called by muse, mutect2, varscan2
- CTTNBP2 | c.3332A>T p.Q1111L | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs191024761, COSV50459693; called by muse, varscan2
- DCPS | c.48C>G p.D16E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs141030550; called by muse, mutect2, varscan2
- DDX10 | c.2071A>T p.T691S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.056); catalogued as COSV59439074; called by muse, mutect2, varscan2
- DNER | c.1100C>A p.A367E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.258); catalogued as COSV59174461; called by muse, mutect2, varscan2
- DST | c.20378G>A p.R6793H (on ENST00000361203 / NM_001374722.1; = p.R4490H on NM_015548.5) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747281179, COSV55012300; called by muse, mutect2, varscan2
- EMCN | c.569-2A>C p.X190_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV56463362; called by muse, mutect2, varscan2
- ERICH6 | c.1888T>C p.Y630H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55802726; called by muse, mutect2, varscan2
- FAM124B | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV54739795; called by muse, mutect2, varscan2
- FAM135B | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759111682, COSV52748697; called by muse, mutect2, varscan2
- FUT3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57487730; called by muse, mutect2, varscan2
- FUT9 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV56154723; called by muse, mutect2, varscan2
- GALNT13 | c.1533A>G p.R511= | Splice Region (SNP) | VAF 9/70 reads (13%) | catalogued as COSV67235419; called by muse, mutect2, varscan2
- GLI3 | c.3286G>A p.V1096M | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as rs762642157, COSV67891457; called by muse, mutect2, varscan2
- GLRA2 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV54342361, COSV54346633; called by muse, mutect2, varscan2
- GNAS | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as COSV58344557; called by muse, mutect2, varscan2
- GPER1 | c.914C>A p.T305K | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52470381; called by muse, mutect2, varscan2
- IGFBP2 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV52081178; called by muse, mutect2, varscan2
- KCNG1 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs1273123579, COSV100857014, COSV65369026; called by muse, mutect2, varscan2
- KCNH8 | c.2329A>C p.T777P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60466821; called by muse, mutect2, varscan2
- KCNK9 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV57287255; called by muse, mutect2, varscan2
- LAMA3 | c.9694C>G p.P3232A (on ENST00000313654 / NM_198129.4; = p.P1623A on NM_000227.6) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52541701; called by muse, mutect2, varscan2
- LIMA1 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV57968053; called by muse, mutect2, varscan2
- LRP1B | c.468A>C p.Q156H | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV67264732; called by muse, mutect2, varscan2
- LRRC4B | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868278165, COSV65350666; called by muse, mutect2
- LRRC52 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 28/154 reads (18%) | catalogued as COSV54233425; called by muse, mutect2, varscan2
- LRRC66 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs762326234, COSV58632313, COSV58636341; called by muse, mutect2, varscan2
- MED13L | c.2203C>A p.Q735K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.021); catalogued as COSV56128151; called by muse, mutect2, varscan2
- MICALL1 | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV53242998; called by muse, mutect2, varscan2
- MUC16 | c.13139C>A p.T4380K | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs762271571, COSV67488139; called by muse, mutect2, varscan2
- MYH13 | c.5378C>T p.T1793M | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs773006118, COSV52823185; called by muse, mutect2, varscan2
- MYH13 | c.2001G>T p.R667S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV52821408, COSV52840180; called by muse, mutect2, varscan2
- NAV3 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs1335504706, COSV57092270; called by muse, mutect2, varscan2
- NEB | c.1219T>C p.F407L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.358); catalogued as COSV51452366; called by muse, mutect2, varscan2
- NEXMIF | c.1375T>A p.C459S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as COSV50083478; called by muse, mutect2, varscan2
- NPL | c.948G>T p.L316F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV51127166; called by muse, mutect2
- NPPA | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as rs765848358, COSV56742666; called by muse, mutect2, varscan2
- OSBP | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55665184; called by muse, mutect2, varscan2
- PADI2 | c.1874T>A p.L625Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64954656; called by muse, mutect2, varscan2
- PANX2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50292394; called by muse, mutect2, varscan2
- PCDHAC2 | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as rs782591270, COSV53850572; called by muse, mutect2, varscan2
- PCLO | c.10978G>T p.D3660Y | Missense Mutation (SNP) | VAF 59/361 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61644311, COSV61660177; called by muse, mutect2, varscan2
- PCNT | c.9239T>A p.L3080Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV64032295; called by muse, mutect2, varscan2
- PDYN | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1171241754, COSV54103029; called by muse, mutect2, varscan2
- PICK1 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.521); catalogued as COSV100259879, COSV57636939; called by muse, mutect2, varscan2
- PIGG | c.900C>T p.P300= | Splice Region (SNP) | VAF 16/33 reads (48%) | catalogued as rs1343365553, COSV56317314; called by muse, mutect2, varscan2
- PLG | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51985563; called by muse, mutect2, varscan2
- PRSS1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs141011596; called by muse, mutect2, varscan2
- PSMC2 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.161); catalogued as COSV50793647; called by muse, mutect2, varscan2
- PSPC1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV58890308; called by muse, mutect2, varscan2
- PTPRT | c.1898T>G p.L633R | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV62011954; called by muse, mutect2, varscan2
- R3HDML | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53837533; called by muse, mutect2, varscan2
- RAI1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55397851; called by muse, mutect2, varscan2
- RALY | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1193755710, COSV55781188; called by muse, mutect2, varscan2
- RBM33 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55296815, COSV55299687; called by muse, mutect2, varscan2
- RGL4 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs775973654, COSV51945148; called by muse, mutect2, varscan2
- RPH3A | c.299T>A p.L100Q (on ENST00000389385 / NM_001143854.2; = p.L96Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66992610; called by muse, mutect2, varscan2
- SAMD9 | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs1442318478, COSV66076942; called by muse, mutect2
- SASS6 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs1260169868, COSV54929858; called by muse, mutect2, varscan2
- SCN8A | c.4722T>G p.F1574L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs1377093609, COSV61991468; called by muse, mutect2, varscan2
- SLC39A12 | c.1852T>C p.Y618H (on ENST00000377369 / NM_001145195.2; = p.Y581H on NM_152725.3) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745314863, COSV66201871; called by muse, mutect2, varscan2
- SNPH | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs139099290; called by muse, mutect2, varscan2
- SRGAP2 | c.1980A>T p.Q660H (on ENST00000624873 / NM_001170637.4; = p.Q661H on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55342159; called by muse, mutect2, varscan2
- SYNE1 | c.16849C>T p.R5617* (on ENST00000367255 / NM_182961.4; = p.R5546* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs758379604, COSV55068980; called by muse, mutect2, varscan2
- SYNGR3 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as COSV50192542; called by muse, mutect2
- SYTL2 | c.1282A>T p.T428S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60362669; called by muse, mutect2, varscan2
- TBC1D20 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 55/388 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.123); catalogued as COSV62613332; called by muse, mutect2, varscan2
- TJP3 | c.2261A>T p.Q754L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53665163; called by muse, mutect2, varscan2
- TRAK1 | c.2245A>G p.I749V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59646965; called by muse, mutect2, varscan2
- TSPOAP1 | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs754040639, COSV52104362; called by muse, mutect2, varscan2
- TTLL5 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773542134, COSV54027350; called by muse, mutect2, varscan2
- TTN | c.49181C>T p.A16394V (on ENST00000591111; = p.A8970V on NM_003319.4) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | PolyPhen benign (0.006); catalogued as rs182445366, COSV60188793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.18617C>A p.T6206K (on ENST00000591111; = p.T5279K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | PolyPhen benign (0.023); catalogued as COSV60289482; called by muse, mutect2, varscan2
- UBAC1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 25/73 reads (34%) | catalogued as COSV65614592; called by muse, mutect2, varscan2
- ZFHX4 | c.3162C>A p.Y1054* | Nonsense Mutation (SNP) | VAF 78/245 reads (32%) | catalogued as COSV51490691; called by muse, mutect2, varscan2
- ZNF479 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV58642846; called by muse, mutect2, varscan2
- ADAMTSL1 | c.55del p.L19Cfs*3 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by pindel, varscan2
- ATMIN | c.500_503del p.C167Lfs*13 | Frame Shift Del (DEL) | VAF 32/154 reads (21%) | called by mutect2, pindel, varscan2
- CFHR5 | c.431_433del p.X144_splice | Splice Site (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- EHBP1 | c.1031dup p.N344Kfs*14 | Frame Shift Ins (INS) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- MUL1 | c.392dup p.H131Qfs*27 | Frame Shift Ins (INS) | VAF 34/106 reads (32%) | called by mutect2, pindel, varscan2
- SLC35C2 | c.605_635del p.F202Sfs*87 | Frame Shift Del (DEL) | VAF 10/107 reads (9%) | called by mutect2, pindel
- SLC8A2 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2
- TFPI | c.307del p.M103Cfs*11 | Frame Shift Del (DEL) | VAF 46/60 reads (77%) | called by mutect2, varscan2
- TMEM39A | c.554dup p.N185Kfs*22 | Frame Shift Ins (INS) | VAF 31/61 reads (51%) | called by mutect2, pindel, varscan2
- TRIM37 | c.1841_1850del p.I614Kfs*3 | Frame Shift Del (DEL) | VAF 32/171 reads (19%) | called by mutect2, pindel, varscan2
- ZFPM2 | c.3035del p.N1012Mfs*16 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- ABCA12 | c.4878A>G p.K1626= (on ENST00000272895 / NM_173076.3; = p.K1308= on NM_015657.3) | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as COSV55972631; called by muse, mutect2, varscan2
- ACACA | c.3700C>T p.L1234= | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ADCY8 | c.3306C>T p.G1102= | Silent (SNP) | VAF 152/296 reads (51%) | catalogued as rs145809062; called by muse, mutect2, varscan2
- AKR1C2 | c.792G>A p.G264= | Silent (SNP) | VAF 7/61 reads (11%) | called by mutect2, varscan2
- BCHE | c.945A>G p.S315= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52261026; called by muse, mutect2, varscan2
- CYP24A1 | c.1167G>A p.P389= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs200816735, COSV53774892; called by muse, mutect2, varscan2
- EPB41L1 | c.459C>T p.D153= | Silent (SNP) | VAF 37/361 reads (10%) | catalogued as COSV52443336; called by muse, mutect2, varscan2
- FAT4 | c.14622A>G p.Q4874= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as rs761187408, COSV58672325, COSV58674006, COSV58679733; called by muse, mutect2
- FLNA | c.4524C>A p.T1508= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100775219, COSV61049773; called by muse, mutect2, varscan2
- KRT39 | c.1161C>A p.S387= | Silent (SNP) | VAF 1523/3186 reads (48%) | catalogued as rs1010001617, COSV62917896; called by muse, mutect2, varscan2
- LUZP2 | c.627T>G p.T209= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV61216228; called by muse, mutect2, varscan2
- MARCHF6 | c.1059G>A p.L353= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs976629594, COSV56880536; called by muse, mutect2, varscan2
- MDGA2 | c.1995C>T p.Y665= (on ENST00000399232 / NM_001113498.2; = p.Y367= on NM_182830.4) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs368219229, COSV62081391; called by muse, mutect2, varscan2
- MUC5B | c.10050C>T p.S3350= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101500308; called by muse, mutect2, varscan2
- MYO16 | c.2259G>A p.V753= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV51779049; called by muse, mutect2, varscan2
- OBSL1 | c.3426C>T p.H1142= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs377322292; called by muse, mutect2, varscan2
- PCDHA8 | c.1086C>T p.D362= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV65339088; called by muse, mutect2, varscan2
- PPP1R21 | c.522C>T p.N174= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs1459144744, COSV54288197; called by muse, mutect2, varscan2
- PREX2 | c.2931G>A p.S977= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs570753617, COSV55795646; called by muse, mutect2
- S1PR5 | c.1140C>T p.G380= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs765367534, COSV61014508; called by muse, mutect2, varscan2
- SAMD9 | c.2826A>G p.L942= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1211325591, COSV101180252; called by muse, mutect2
- SFRP4 | c.315C>T p.R105= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as rs761497415, COSV52259009, COSV99554729; called by muse, mutect2, varscan2
- SGIP1 | c.957C>T p.S319= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as rs778259059, COSV52777366; called by muse, mutect2, varscan2
- SGIP1 | c.1302G>A p.P434= | Silent (SNP) | VAF 81/201 reads (40%) | catalogued as rs1419554144, COSV52765521; called by muse, mutect2, varscan2
- SORBS3 | c.1569C>T p.D523= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs146729720, COSV53553235; called by muse, mutect2, varscan2
- TENM4 | c.5886G>A p.A1962= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs775873994, COSV53662683; called by muse, mutect2, varscan2
- TFCP2L1 | c.234A>T p.R78= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV55294536; called by muse, mutect2, varscan2
- ZFHX4 | c.2079G>A p.T693= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV50650428, COSV99266889; called by muse, mutect2, varscan2
- ZNF12 | c.597T>C p.Y199= (on ENST00000405858 / NM_016265.4; = p.Y161= on NM_006956.3) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs1023374644, COSV61245403; called by muse, mutect2, varscan2
- ZNF134 | c.1161T>C p.L387= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as COSV68696797; called by muse, mutect2, varscan2
- DCHS2 | n.1436G>A | RNA (SNP) | VAF 30/72 reads (42%) | catalogued as COSV100251580, COSV59737578; called by muse, mutect2, varscan2
- MECP2 | c.-143C>T | 5'UTR (SNP) | VAF 12/12 reads (100%) | catalogued as COSV100318108; called by muse, varscan2
- OR52A4P | chr11:5120791 del A | 3'Flank (DEL) | VAF 19/88 reads (22%) | catalogued as rs769032953; called by mutect2, varscan2
- RRP7A | c.*3807A>G | 3'UTR (SNP) | VAF 12/57 reads (21%) | catalogued as rs1360484105; called by muse, mutect2, varscan2
